Gene-level copy-number profile of tumor specimen ALCH-B2QQ-TTP1-A from ALCHEMIST case ALCH-B2QQ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 53.9 years (19,705 days).
Specimen ALCH-B2QQ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d32caf1b-27ee-4cc0-98aa-87cb5abaa855.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2QQ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/4f937d1e-4bcb-4be5-a49a-6a19e1e9e0ad

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 548; copy number 2: 57,679; copy number 3: 127; copy number 4: 14; copy number 5: 2; copy number 6: 1; copy number 9: 2; copy number 14: 1.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:129,632,019–129,632,492, 1 gene: AC023162.1.
- chr6:70,566,917–70,609,334, 3 genes: SDHAF4, AL583856.2, AL583856.1.
- chr7:1,614,590–1,615,325, 1 gene: TFAMP1.
- chr7:4,811,188–4,811,289, 1 gene (within-gene range 0–2): Y_RNA.
- chr12:132,623,753–132,687,376, 1 gene: POLE.
- chr14:18,333,726–18,419,273, 4 genes: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:134,114,681–134,151,865, 1 gene, copy number 5 (within-gene range 2–5): TCF7.
- chr7:1,570,073–1,589,626, 1 gene, copy number 5 (within-gene range 2–5): PSMG3-AS1.

Autosomal genes at a single copy (total copy number 1): 539. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
